FM case AD9474 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/79db2628-7e8f-4458-800d-21a52bc15f49

Female, 56.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the rectum; primary biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
